Somatic mutation profile of tumor specimen 0DVSBU from CCDI case PBCMUC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 14.3 years (5,235 days).
Specimen 0DVSBU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90b4b26d-b665-4b41-8f1a-0e5c267892b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSC7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ca0075c-b13f-4acf-8cba-cee8fbe8da28

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD14 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 132/814 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.14); catalogued as rs141847758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHIPL1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 117/531 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs1198049672; called by muse, mutect2, varscan2
- ERGIC3 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 318/1352 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
